Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8KK, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8KK-01A (Primary Tumor).

[page 1 of 2]
Department of Pathology

Page 1 of 3

Unit No

REPORT Tel:

Clinical Consultant & Location

Sex

This Copy For:

SPECIMEN

Left (enucleated) eye

CLINICAL DETAILS

Left choroidal melanoma.
(1): ? orbital invasion.
See diagram.
19.5 x 17.1 x (10.9)mm. 40% SRF.

MACROSCOPIC DESCRIPTION

A fresh, intact left globe.

Dimensions: Axial 26mm, Horizontal 24.5mm, Vertical 25mm

Cornea: Horizontal 11.6mm, Vertical 11mm

Optic nerve
Length 7mm, Diameter 4mm

On trans-illumination, a large shadow is seen over almost all medial half of the globe.

Plane of section: horizontal

Intraocular description:

On opening, a large solitary pigmented choroidal mass is seen associated with probable focal underlying extrascleral extension.

Tumour size

LBD 17.5mm, Height 12.6mm

MICROSCOPY

Sections show a partially pigmented choroidal melanoma consisting predominantly of spindle cells. Tumour cells express Melan-A and HSP 27 (score 2). There are approximately 7 mitotic figures in 40 high power fields. Closed loops are focally present. The lymphocytic infiltrate within the tumour is minimal. Scattered macrophages are present. Tumour necrosis is not seen. Bruch's membrane

ICD-O-3

Melanoma, spindle cell, type B
8774/3

Site: Choroid C69.3

9/5/17/14

Reported:

Pathologist:

Electronically Verified:

[page 2 of 2]
Department of Pathology

Page 2 of 3

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]	

This Copy For: [REDACTED]

appears breached in the sections examined. There is no tumour extension through optic nerve or vortex veins examined. Tumour, however, infiltrates through the sclera emerging on scleral surface and loosely attached episcleral tissue. Therefore completeness of excision may not be guaranteed.

Elsewhere, the cornea shows no significant abnormality. The anterior chamber angles are open and the anterior chamber is deep. The iris shows no significant abnormality but the ciliary body appears atrophic with hyalinisation of ciliary processes. The lens shows glassy appearance. Retina overlying the tumour is slightly atrophic.

DIAGNOSIS

Left eye, enucleation: Choroidal melanoma of predominantly spindle cell type with extrascleral infiltration.

SUMMARY

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	2= Spindle B
CT LOOPS	2= Closed loops
NECROSIS	No
PIGMENTATION	Yes
LYMPHOCYTIC INFILTRATION	No
MITOTIC FREQUENCY	7 /40 HPF
DIFFUSE MELANOMA	No
SPREAD	3= Trans-scleral
CLEARANCE	1= Inadequate
HSP-27 POSITIVITY	2= 21-70%
LARGE DIAMETER	17.5 mm

Reported:

Pathologist:

Electronically Verified:

Primary Tumour Site Discrepancy		
Prior Discrepancy History		

Source: NCI Genomic Data Commons file e8f83ee7-1020-4b76-9187-fadbeb99f9bb (TCGA-VD-A8KK.2C7A9333-9CCF-4E1E-A3DC-BE9ED78858B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).